Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A8VB, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A8VB-01A (Primary Tumor).

Date of Surgery:

ICDO-3

Tumor, peripheral nerve
sheath malignant 9540/3
Site ^{C&F} Back NOS C49.6
^{path} Trunk NOS C49.6
9/12/14

FINAL DIAGNOSIS:

1. SKIN of RIGHT BACK, WIDE RE- EXCISION:
- MALIGNANT PERIPHERAL NERVE SHEET TUMOR.
- Size of Tumor-3.5x3x3 cm.
- Margins of Resection-negative for tumor.
- NEUROFIBROMAS.
- Dermal Fibrous scarring at previous biopsy site
2. SKIN of RIGHT FLANK, ADDITIONAL MARGINS: EXCISION:
- NEUROFIBROMAS
- Negative for residual malignant peripheral nerve sheet tumor.

GROSS DESCRIPTION:

1. WIDE RE-EXCISION, SARCOMA OF RIGHT BACK:
Received broad ellipse of skin with underlying abundant amount of subcutaneous adipose tissue. Specimen measures 11x5x3 cm. Ellipse of skin with healing incisional scar and posterior third of the specimen shows small sessile skin tags or nodular like appearance. The largest measures 0.5 cm. in diameter. On cut section, central portion of the specimen shows an ill defined margin tan yellow fibrous tumor measures 3.5x3x3 cm. Grossly, tumor is within 5 mm. from nearest designated inferior margin. Inferior-orange, superior-red, anterior-blue, deep-black.
2. ADDITIONAL TISSUE RIGHT FLANK
Specimen consists of 14.0x1.4 cm. oriented skin ellipse with attached subcutaneous soft tissue measuring 7.0x1.5x2 cm. Single suture designates lateral margin. (Margin was inked black). The skin surface shows numerous nodular skin tags measuring 0.8 cm. in greatest dimension; the skin is otherwise unremarkable. On cut sections, subcutis show no grossly identifiable residual tumor. Sections submitted in 6 cassettes.

Source: NCI Genomic Data Commons file 68a86226-1845-48d7-a65c-53c3df88b0cb (TCGA-QQ-A8VB.56F1B5CC-DEEC-49F0-A58B-3F564638842E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).